Gene-level copy-number profile of tumor specimen HTMCP-03-06-02001-01A from CGCI case HTMCP-03-06-02001, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2.
Specimen HTMCP-03-06-02001-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9671bf06-d6ca-4c7d-91ab-ee5135efed39.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02001-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/620a2331-5062-42c7-86bc-fd7078ee930b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,531; copy number 2: 51,056; copy number 3: 4,546; copy number 4: 678; copy number 5: 582; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 584 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:168,249,522–168,830,599, 1 gene, copy number 5 (within-gene range 3–5): EGFEM1P.
- chr3:168,475,198–198,123,232, 582 genes, copy number 5–6 (broad region; genes not listed).
- chr5:710,355–784,729, 1 gene, copy number 5 (within-gene range 4–5): ZDHHC11B.

Autosomal genes at a single copy (total copy number 1): 1,531. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
